Surgical pathology report (de-identified scan), TCGA case TCGA-CR-6467, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Vanderbilt University, specimen TCGA-CR-6467-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Accession Number: [REDACTED]

Final Report

DIAGNOSIS:

- 1) PHARYNX, WALL, RIGHT, LATERAL, BIOPSY: INVOLVED BY POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA.
- 2) NECK, LEVEL I, RIGHT EXCISION: 4 LYMPH NODES, NEGATIVE FOR MALIGNANCY; BENIGN SUBMANDIBULAR SALIVARY GLAND, NEGATIVE FOR MALIGNANCY.
- 3) NECK, LEVEL IIB, RIGHT, EXCISION: 8 LYMPH NODES, NEGATIVE FOR MALIGNANCY.
- 4) NEC, LEVEL IIA, 3 AND 4, RIGHT, EXCISION: METASTATIC SQUAMOUS CELL CARCINOMA INVOLVING 1 OF 29 LYMPH NODES, 3.0 cm IN GREATEST DIMENSION.
- 5) TONSIL, RIGHT, EXCISION: INVOLVED BY POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA, 3.2 cm IN GREATEST DIMENSION INVOLVING A CAUTERIZED LATERAL RESECTION MARGIN.
- 6) ORAL CAVITY, RETROMANDIBULAR, TRIGONE, BIOPSY: MINOR SALIVARY GLAND TISSUE, NEGATIVE FOR MALIGNANCY.
- 7) TONSILLAR POLE, SUPERIOR, BIOPSY: MINOR SALIVARY GLAND TISSUE, NEGATIVE FOR MALIGNANCY.
- 8) SOFT PALATE, "GLANDS", BIOPSY: MINOR SALIVARY GLAND TISSUE, NEGATIVE FOR MALIGNANCY.

Electronically signed by: [REDACTED]

CLINICAL DATA

Clinical Features: unspecified - [REDACTED]

Operator: Dr. [REDACTED]

Operation: radical resection of tonsil

Operative Findings: unspecified

Operative Diagnosis: unspecified

Tissue Submitted: 1)right lateral pharyngeal wall; 2)right level 1 contents; 3)right level IIB; 4)level 2A, 3&4 right neck

[page 2 of 3]
GROSS DESCRIPTION:

1) SOURCE: Pharyngeal wall, right lateral

Received fresh is a tan-pink soft tissue fragment, 0.4 cm in greatest dimension. The entire specimen is submitted for frozen section.

Summary of sections: 1AFSC, 1/1.

2) SOURCE: Neck, right level I contents

Received fresh is a large fragment of red-pink and brown fibroadipose tissue, lymph node candidates, and minor salivary gland. The entire specimen measures 5.0 x 2.5 x 1.5 cm. The minor salivary gland measures 3.5 x 2.0 x 1.0 cm. A thorough lymph node dissection is performed and reveals four lymph node candidates ranging from 0.5 to 2.0 cm in greatest dimension. The minor salivary gland is serially sectioned and reveals a lobular, yellow-tan architecture with no suspicious nodules or masses identified. All lymph node candidates and a representative section of minor salivary gland are submitted.

Summary of sections: 2A, one node, 2/1; 2B, two nodes, smallest inked black, 3/1; 2C, one node, 2/1; 2D, gland, 1/1.

3) SOURCE: Neck, right level II B

Received fresh is a tan-yellow and pink cauterized soft tissue fragment, 3.0 x 2.5 x 1.0 cm. The entire outer surface is inked black. The specimen is mainly fibrotic, and serially sectioned to reveal yellow-pink parenchymal surface with no suspicious nodules or masses. Representative sections are submitted in three cassettes.

Summary of sections: 3A-3C, 1/1 each.

4) SOURCE: Neck, right level 2A, 3,4

Received fresh is a large soft tissue fragment, ranging from red-pink to tan-yellow, measuring 10.0 x 6.0 x 2.0 cm. There is a firm, enlarged lymph node measuring 3.0 cm in greatest dimension, grossly involved by tumor. A portion of this lymph node is submitted for research purposes.

A thorough dissection reveals 23 lymph node candidates ranging from 0.4 to 1.8 cm in greatest dimension. All lymph node candidates are submitted.

Summary of sections: 4A, largest grossly involved node and possible lymph node candidates, 2/1; 4B-4E, five lymph node candidates each, 5/1 each; 4F-4H, one lymph node candidate, 2/1.

5) SOURCE: Tonsil, right

Received fresh is an enlarged, tan-pink and red tonsil, 4.0 x 2.5 x 2.0 cm. The majority of the specimen has a cauterized, roughened, outer surface. There is a squamous mucosa present with a deep crypt with a necrotic-appearing architecture. The cauterized surface is inked entirely black, the specimen is serially sectioned and reveals a majority of the tonsil to be involved by an ill-defined, tan-yellow, firm mass, suspicious for carcinoma, measuring 3.2 in greatest dimension. The tumor appears to involve the deep margin. Representative sections are submitted.

[page 3 of 3]
Summary of sections: 5A, 1/1; 5B-5C, 3/1.

6) SOURCE: Retro mandibular trigone

Received fresh is a cauterized, tan-pink soft tissue fragment, 1.0 cm in greatest dimension. The entire specimen is inked black. The specimen is bisected and submitted entirely in one cassette.

Summary of sections: 6A, 2/1.

7) SOURCE: Superior Tonsillar Pole

Received fresh is a small tan-brown, cauterized soft tissue fragment, 0.5 cm in greatest dimension. The specimen is bisected and submitted entirely in one cassette.

Summary of sections: 7A, 2/1.

8) SOURCE: Soft palate glands

Received fresh is a tan-brown and pink cauterized, soft tissue fragment, 1.4 x 0.8 x 0.2 cm. The specimen is bisected and submitted entirely in one cassette.

Summary of sections: 8A, 2/1.

[REDACTED]

SURGICAL PATHOLOGY INTRAOPERATIVE CONSULTATION

1) SOURCE: Pharyngeal wall, right lateral

FROZEN SECTION DIAGNOSIS: INVOLVED BY TUMOR. [REDACTED]

Electronically signed by: [REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 2d14d301-0d95-40fb-8ae3-085146c68d1c (TCGA-CR-6467.6904AC1F-B946-4898-949D-C232B8C89910.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).